Somatic mutation profile of tumor specimen TCGA-TS-A7OY-01A (aliquot TCGA-TS-A7OY-01A-11D-A34C-32) from TCGA case TCGA-TS-A7OY, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.2 years (22,720 days).
Specimen TCGA-TS-A7OY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dc3c166-1f0e-4fb3-80f6-1a4dfe8b498a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7OY-10A (Blood Derived Normal), aliquot TCGA-TS-A7OY-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/150b3577-9f5e-48e4-a3b7-2e0b654d81b7

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C9orf24 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs772881011; called by muse, mutect2
- DNMT3A | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs759747476, COSV53047432; called by muse, mutect2
- KMT2C | c.14365C>T p.R4789* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as COSV51326172; called by muse, mutect2
- LDOC1 | c.420A>C p.E140D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs937471876; called by muse, mutect2, varscan2
- NF2 | c.482del p.G161Dfs*13 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV58526670; called by mutect2, pindel, varscan2
- OR1D2 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs750765355; called by muse, mutect2, varscan2
- PLXNC1 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as rs751117319, COSV51568591; called by muse, mutect2, varscan2
- PPRC1 | c.4159A>G p.M1387V | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs201606390; called by muse, mutect2, varscan2
- SERINC2 | c.115C>T p.R39C (on ENST00000373709 / NM_178865.5; = p.R43C on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782394996; called by muse, mutect2, varscan2
- ABI3BP | c.2471G>C p.G824A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AL645922.1 | c.2345G>A p.S782N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCT2 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, varscan2
- COASY | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EIF4G1 | c.3242A>G p.N1081S (on ENST00000346169 / NM_198241.3; = p.N886S on NM_004953.5) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2
- GNAT1 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- GOLGB1 | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.8413G>A p.V2805I | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTCH1 | c.2507A>G p.E836G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPS1 | c.1337_1362del p.S446Lfs*14 (on ENST00000220888 / NM_001330599.2; = p.S459Lfs*14 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel
- HPS3 | c.834A>G p.G278= | Silent (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2, varscan2
- LLGL2 | c.2613C>T p.G871= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs145181414; called by muse, mutect2, varscan2
- NALCN | c.1263G>A p.A421= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs140469887; called by mutect2, varscan2
- NR5A2 | c.1212C>T p.F404= (on ENST00000367362 / NM_205860.3; = p.F358= on NM_003822.5) | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV52657793; called by muse, mutect2, varscan2
- RUNX1 | c.60G>A p.L20= (on ENST00000344691 / NM_001001890.3; = p.L47= on NM_001754.5) | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- TLN2 | c.618A>G p.V206= | Silent (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
